Somatic mutation profile of tumor specimen TCGA-ZG-A9L4-01A (aliquot TCGA-ZG-A9L4-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9L4, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.3 years (22,388 days).
Specimen TCGA-ZG-A9L4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe918971-68ff-48a9-a1a7-f4c2444b213d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9L4-10A (Blood Derived Normal), aliquot TCGA-ZG-A9L4-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8df2077e-175a-4799-b56c-35736852700c

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Nonsense Mutation 3, Silent 3, 3'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs763825500, COSV100837360; called by muse, mutect2, varscan2
- CIITA | c.3326C>T p.T1109M | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1013962316, COSV60855883; called by muse, mutect2
- DEFB129 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99857510; called by muse, mutect2, varscan2
- HIC1 | c.79C>T p.P27S (on ENST00000322941 / NM_001098202.1; = p.P8S on NM_006497.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99558551; called by muse, mutect2
- KRT27 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV56971177; called by muse, mutect2, varscan2
- NAPRT | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs775060116, COSV99435277; called by muse, mutect2, varscan2
- NDST3 | c.410T>A p.L137* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99630527, COSV99631402; called by muse, mutect2
- NUP43 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100462241; called by muse, mutect2
- OR10G8 | c.350T>A p.M117K | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101461857; called by muse, mutect2
- OR6Q1 | c.406T>G p.Y136D | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110343; called by muse, mutect2
- PCDH11Y | c.1646G>A p.R549H (on ENST00000400457 / NM_032973.2; = p.R538H on NM_032971.3) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1381302441, COSV53089767; called by muse, mutect2, varscan2
- PHYHIPL | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs530007000, COSV100874220; called by muse, mutect2, varscan2
- POLG | c.3689C>T p.S1230F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99174987; called by muse, mutect2
- PRSS58 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | catalogued as rs766468973, COSV73488547; called by muse, mutect2, varscan2
- PTPRU | c.3107G>C p.G1036A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100113447; called by muse, mutect2, varscan2
- RAB11FIP4 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100365646; called by muse, mutect2
- SLC12A5 | c.1561G>T p.A521S (on ENST00000454036 / NM_001134771.2; = p.A498S on NM_020708.5) | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99716550; called by muse, mutect2
- THSD7B | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99756049; called by muse, mutect2, varscan2
- WDR64 | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV100843954; called by muse, mutect2, varscan2
- SNX2 | c.1250G>A p.W417* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- C3 | c.381C>T p.S127= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs917865494, COSV55582348; called by muse, mutect2
- EDC4 | c.2274C>T p.S758= | Silent (SNP) | VAF 10/161 reads (6%) | catalogued as COSV100197736; called by muse, mutect2
- PRR3 | c.156C>T p.G52= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1202243526, COSV100925438; called by muse, mutect2, varscan2
- MORF4 | n.540C>A | RNA (SNP) | VAF 11/193 reads (6%) | called by muse, mutect2
- OR6N1 | c.*1G>T | 3'UTR (SNP) | VAF 21/100 reads (21%) | catalogued as rs1188119766, COSV100625263; called by muse, mutect2, varscan2
